MMRF case MMRF_1577 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/11ae0cc0-7d9e-45ab-b3f3-854d1562f77d

Demographics
Sex at birth: male; Race: white; Age at index: 42 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 42.0 years (15,349 days); ISS stage: II; Days to last known disease status: 1,263 days (3.5 years); Days to last follow up: 1,263 days (3.5 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 128 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 149 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 233 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 86 days; Days to treatment end: 233 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 128 days; Days to treatment end: 152 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 172 days; Days to treatment end: 172 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 254 days; Days to treatment end: 254 days.
   Treatment given: Therapeutic agents: Bortezomib + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 340 days; Days to treatment end: 382 days (1.0 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 340 days; Days to treatment end: 539 days (1.5 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 396 days (1.1 years); Days to treatment end: 1,061 days (2.9 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 535 days (1.5 years); Days to treatment end: 562 days (1.5 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 563 days (1.5 years); Days to treatment end: 589 days (1.6 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,081 days (3.0 years).
   Treatment given: Therapeutic agents: Other; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,081 days (3.0 years); Days to treatment end: 1,227 days (3.4 years).
   Treatment given: Therapeutic agents: Other; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,228 days (3.4 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,263.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -4 (ECOG 1): M Protein 7.88 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 10.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.142 mg/dL; Immunoglobulin G 95.4 g/L; Immunoglobulin A 0.17 g/L; Beta 2 Microglobulin 2.92 µg/mL; Lactate Dehydrogenase 2.87 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 8.4 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 168 ×10⁹/L; Creatinine 86 µmol/L; Blood Urea Nitrogen 4.2 mmol/L; Calcium 2.46 mmol/L; Albumin 28 g/L; Total Protein 14.9 g/dL; Glucose 5.7 mmol/L; C-Reactive Protein 0.1 mg/dL.
- Day 79 (ECOG 1): M Protein 4.72 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.028 mg/dL; Immunoglobulin G 65.8 g/L; Immunoglobulin A 0.06 g/L; Immunoglobulin M 0.1 g/L; Lactate Dehydrogenase 2.48 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 11.9 ×10⁹/L; Absolute Neutrophil 8.8 ×10⁹/L; Platelets 290 ×10⁹/L; Creatinine 70 µmol/L; Blood Urea Nitrogen 6.2 mmol/L; Calcium 2.2 mmol/L; Albumin 37.9 g/L; Total Protein 10.3 g/dL; Glucose 12.2 mmol/L.
- Day 180 (ECOG 1): M Protein 1.13 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.31 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.721 mg/dL; Immunoglobulin G 15 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.14 g/L; Beta 2 Microglobulin 1.86 µg/mL; Lactate Dehydrogenase 3.27 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 12.1 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 69 ×10⁹/L; Creatinine 74 µmol/L; Blood Urea Nitrogen 6.9 mmol/L; Calcium 2.26 mmol/L; Albumin 39 g/L; Total Protein 7.4 g/dL; Glucose 10.4 mmol/L.
- Day 253 (ECOG 1): M Protein 9.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.71 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.21 mg/dL; Immunoglobulin G 12.6 g/L; Immunoglobulin A 0.51 g/L; Immunoglobulin M 0.3 g/L; Beta 2 Microglobulin 2.28 µg/mL; Lactate Dehydrogenase 2.13 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 1.2 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 111 ×10⁹/L; Creatinine 61 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.24 mmol/L; Albumin 34 g/L; Total Protein 7 g/dL; Glucose 6.6 mmol/L.
- Day 366 (ECOG 1): M Protein 6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.907 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.526 mg/dL; Immunoglobulin G 12.2 g/L; Immunoglobulin A 12.2 g/L; Immunoglobulin M 0.98 g/L; Beta 2 Microglobulin 2.8 µg/mL; Lactate Dehydrogenase 2.63 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 7.5 ×10⁹/L; Absolute Neutrophil 5 ×10⁹/L; Platelets 126 ×10⁹/L; Creatinine 75 µmol/L; Blood Urea Nitrogen 3.2 mmol/L; Calcium 2.28 mmol/L; Albumin 42.7 g/L; Total Protein 7 g/dL; Glucose 6.1 mmol/L.
- Day 437 (ECOG 1): M Protein 4.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.71 mg/dL; Immunoglobulin G 12.2 g/L; Immunoglobulin A 0.09 g/L; Immunoglobulin M 1 g/L; Lactate Dehydrogenase 2.78 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 116 ×10⁹/L; Creatinine 84 µmol/L; Calcium 2.25 mmol/L; Albumin 37 g/L; Total Protein 6.6 g/dL; Glucose 6 mmol/L.
- Day 535 (ECOG 1): M Protein 3.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.18 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.968 mg/dL; Immunoglobulin G 11.2 g/L; Immunoglobulin A 0.06 g/L; Immunoglobulin M 0.31 g/L; Lactate Dehydrogenase 3.3 µkat/L; Hemoglobin 8.93 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 125 ×10⁹/L; Creatinine 80 µmol/L; Blood Urea Nitrogen 3 mmol/L; Calcium 2.13 mmol/L; Albumin 37 g/L; Total Protein 6.5 g/dL; Glucose 6.6 mmol/L.
- Day 647 (ECOG 1): M Protein 3.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.78 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.61 mg/dL; Immunoglobulin G 13.3 g/L; Immunoglobulin A 0.34 g/L; Immunoglobulin M 0.13 g/L; Lactate Dehydrogenase 2.67 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 149 ×10⁹/L; Creatinine 89 µmol/L; Blood Urea Nitrogen 3.9 mmol/L; Calcium 2.18 mmol/L; Albumin 43.1 g/L; Total Protein 7.1 g/dL; Glucose 6.5 mmol/L.
- Day 703 (ECOG 1): M Protein 4.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.17 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.63 mg/dL; Immunoglobulin G 12 g/L; Immunoglobulin A 0.31 g/L; Immunoglobulin M 0.22 g/L; Lactate Dehydrogenase 2.4 µkat/L; Hemoglobin 8.99 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 145 ×10⁹/L; Creatinine 99 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.26 mmol/L; Albumin 41 g/L; Total Protein 7.6 g/dL.
- Day 810 (ECOG 1): M Protein 5.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.78 mg/dL; Immunoglobulin G 16.7 g/L; Immunoglobulin A 0.37 g/L; Immunoglobulin M 0.29 g/L; Lactate Dehydrogenase 2.37 µkat/L; Hemoglobin 9.11 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 157 ×10⁹/L; Creatinine 87 µmol/L; Blood Urea Nitrogen 5.4 mmol/L; Calcium 2.28 mmol/L; Albumin 45.4 g/L; Total Protein 7.7 g/dL; Glucose 7.9 mmol/L.
- Day 871 (ECOG 1): M Protein 6.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.95 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.68 mg/dL; Immunoglobulin G 16.9 g/L; Immunoglobulin A 0.39 g/L; Immunoglobulin M 0.22 g/L; Lactate Dehydrogenase 2.23 µkat/L; Hemoglobin 9.18 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 118 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 5.2 mmol/L; Calcium 2.24 mmol/L; Albumin 39 g/L; Total Protein 7.8 g/dL.
- Day 955 (ECOG 1): M Protein 7.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.13 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.72 mg/dL; Immunoglobulin G 19.3 g/L; Immunoglobulin A 0.46 g/L; Immunoglobulin M 0.17 g/L; Lactate Dehydrogenase 2.5 µkat/L; Hemoglobin 9.05 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 131 ×10⁹/L; Creatinine 91 µmol/L; Blood Urea Nitrogen 5.5 mmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Total Protein 7.7 g/dL.
- Day 1,039 (ECOG 1): M Protein 8.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.27 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.57 mg/dL; Immunoglobulin G 19.5 g/L; Immunoglobulin A 0.53 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 2.42 µkat/L; Hemoglobin 9.11 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 133 ×10⁹/L; Creatinine 93 µmol/L; Calcium 2.23 mmol/L; Albumin 41.7 g/L; Total Protein 7.4 g/dL.
- Day 1,130 (ECOG 1): M Protein 5.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.814 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.772 mg/dL; Immunoglobulin G 10.7 g/L; Immunoglobulin A 0.19 g/L; Immunoglobulin M 0.13 g/L; Beta 2 Microglobulin 1.63 µg/mL; Lactate Dehydrogenase 3.32 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 100 ×10⁹/L; Creatinine 85 µmol/L; Blood Urea Nitrogen 5.3 mmol/L; Calcium 2.17 mmol/L; Albumin 37 g/L; Total Protein 6.5 g/dL; Glucose 12.8 mmol/L.
- Day 1,228 (ECOG 1): M Protein 5.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.196 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.159 mg/dL; Immunoglobulin G 8.61 g/L; Immunoglobulin A 0.12 g/L; Immunoglobulin M 0.1 g/L; Beta 2 Microglobulin 2.14 µg/mL; Lactate Dehydrogenase 3.92 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 128 ×10⁹/L; Creatinine 75 µmol/L; Blood Urea Nitrogen 4.9 mmol/L; Calcium 2.2 mmol/L; Albumin 40 g/L; Total Protein 6.7 g/dL; Glucose 7.7 mmol/L.

Other clinical attributes
- Day -4: Weight: 110 kg; Height: 175 cm.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples)
- Sample MMRF_1577_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -4 days.
- Sample MMRF_1577_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -4 days.
- Sample MMRF_1577_3_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 1,039 days (2.8 years).
